Somatic mutation profile of tumor specimen ALCH-ABXY-TTP1-A (aliquot ALCH-ABXY-TTP1-A-1-0-D-A490-36) from ALCHEMIST case ALCH-ABXY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,593 days).
Specimen ALCH-ABXY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e26b4e5-0a3c-4943-b112-96ebf51b0ebb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABXY-NB1-A (Blood Derived Normal), aliquot ALCH-ABXY-NB1-A-1-0-D-A490-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dac1796-313f-48a1-80d0-6dfe094b4858

The open-access MAF lists 220 somatic variants for this specimen: 149 protein-altering or splice-affecting, 43 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 43, Intron 16, Nonsense Mutation 11, 3'UTR 4, 5'UTR 3, RNA 3, Frame Shift Del 2, Splice Region 2, Splice Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 108/403 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 65/156 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACLY | c.1277A>T p.N426I | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs965885161; called by muse, mutect2
- ADAMTS18 | c.3373G>T p.A1125S | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV51410187, COSV51418605; called by muse, mutect2
- ARFGEF1 | c.3772C>T p.R1258W | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242748363, COSV51616244; called by muse, mutect2
- ARID1B | c.5692A>T p.K1898* | Nonsense Mutation (SNP) | VAF 23/178 reads (13%) | catalogued as rs1554237613; called by muse, mutect2, varscan2
- CCDC93 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 68/262 reads (26%) | catalogued as COSV60122408; called by muse, mutect2, varscan2
- CDH1 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs764700595, COSV55730853; ClinVar: likely benign; called by muse, mutect2
- CHRNA6 | c.440C>A p.T147N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs1381221205; called by muse, mutect2, varscan2
- COL2A1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs370821294; called by muse, mutect2
- CYP7B1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 22/276 reads (8%) | catalogued as rs1275379862, COSV59582710; called by muse, mutect2
- DLC1 | c.3119C>T p.T1040M (on ENST00000276297 / NM_001348081.2; = p.T603M on NM_006094.5) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs759342089; called by muse, mutect2, varscan2
- EIF4E2 | c.9C>G p.N3K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs370961236; called by muse, mutect2
- ESPL1 | c.4831C>G p.R1611G | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV57761998, COSV99229352; called by muse, mutect2
- FGFR2 | c.2271G>T p.L757F | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100337177; called by muse, mutect2, varscan2
- FLCN | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs1567822713; ClinVar: uncertain significance; called by muse, mutect2
- GPX5 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV69079987; called by muse, mutect2
- HSD17B4 | c.2059G>T p.A687S (on ENST00000414835 / NM_001199291.3; = p.A662S on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/684 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as rs761960298; called by muse, mutect2
- KLHL14 | c.1775A>G p.Y592C | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1362179421; called by muse, mutect2
- MED13L | c.3554A>T p.D1185V | Missense Mutation (SNP) | VAF 131/667 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745505368; called by muse, mutect2, varscan2
- MMEL1 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as rs927596248; called by mutect2, varscan2
- MUC16 | c.34033G>A p.E11345K | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV67443816; called by muse, mutect2, varscan2
- MYH4 | c.1965C>A p.F655L | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV55111331; called by muse, mutect2, varscan2
- NALCN | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51958031; called by muse, mutect2
- NES | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV63962814; called by muse, mutect2, varscan2
- OPRM1 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376950705, CM016141, COSV57686154; called by muse, mutect2
- OR11H1 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99421685; called by mutect2, varscan2
- OR2T1 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV63542062; called by muse, mutect2
- OR6C74 | c.94A>T p.T32S | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.061); catalogued as COSV59605672; called by mutect2, varscan2
- OTOGL | c.6409G>A p.D2137N (on ENST00000547103; = p.D2128N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1252000742, COSV54021668; called by muse, mutect2
- PAX7 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as CM153298, COSV64750886; called by muse, mutect2
- PCDHA3 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.889); catalogued as rs782740317, COSV63539627; called by muse, mutect2
- PCSK6 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.214); catalogued as rs1219187949; called by muse, mutect2
- PGM5 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1554687358; called by muse, mutect2
- POMT1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV61225437; called by muse, mutect2
- PPP3R2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs746497872, COSV62452747; called by muse, mutect2, varscan2
- PQBP1 | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV54431727; called by muse, mutect2, varscan2
- PRELP | c.1054C>A p.L352M | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58117783; called by muse, mutect2, varscan2
- ROBO1 | c.3044G>C p.C1015S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV71398896; called by muse, mutect2
- SEMA5A | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763654731; called by muse, mutect2, varscan2
- SGCZ | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV66023975; called by muse, mutect2
- SGCZ | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101166445; called by muse, mutect2
- SLC17A3 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 50/634 reads (8%) | catalogued as COSV57759644; called by muse, mutect2
- SLC25A35 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749965855; called by muse, mutect2, varscan2
- SORCS3 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV63796298; called by muse, mutect2
- TXNDC16 | c.1839G>T p.M613I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55983296; called by muse, mutect2
- ACOD1 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2
- AFF2 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- ANAPC4 | c.705+1G>T p.X235_splice | Splice Site (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- ANK2 | c.6028C>A p.L2010I | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKRD13B | c.1204A>T p.K402* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- ARHGEF37 | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- ASXL3 | c.5225C>A p.S1742Y | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CBLB | c.2761_2768del p.K921Wfs*3 | Frame Shift Del (DEL) | VAF 30/240 reads (13%) | called by mutect2, pindel
- CCR1 | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by mutect2, varscan2
- CDC14C | c.881A>G p.N294S (on ENST00000428251; = p.N187S on NM_152627.3) | Missense Mutation (SNP) | VAF 43/599 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); called by muse, mutect2
- CEP120 | c.2544G>A p.W848* | Nonsense Mutation (SNP) | VAF 30/470 reads (6%) | called by muse, mutect2
- CHIT1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIAO2A | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2
- CNTNAP5 | c.3484G>T p.A1162S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- COL22A1 | c.1639A>G p.K547E | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- COL3A1 | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 56/630 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A6 | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COPG1 | c.890G>C p.S297T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); called by muse, mutect2
- CPB1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.174); called by muse, mutect2
- CSMD1 | c.9695G>T p.R3232I (on ENST00000520002; = p.R3231I on NM_033225.6) | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- CSMD1 | c.8945C>A p.P2982H (on ENST00000520002; = p.P2981H on NM_033225.6) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.807G>T p.W269C | Missense Mutation (SNP) | VAF 58/828 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTNND2 | c.3562C>G p.H1188D | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CYLC1 | c.659C>G p.P220R | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); called by muse, mutect2
- DACT1 | c.1000T>C p.S334P | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- DNAH3 | c.12197T>C p.V4066A | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.018); called by muse, mutect2
- DOCK11 | c.1869A>T p.E623D | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DST | c.6460A>T p.I2154L | Missense Mutation (SNP) | VAF 66/851 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- EIF4ENIF1 | c.1439A>T p.D480V | Missense Mutation (SNP) | VAF 29/380 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESPL1 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2
- FAM118B | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- FAM78B | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FANCL | c.57C>G p.N19K | Missense Mutation (SNP) | VAF 53/433 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FUT4 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GON4L | c.1369A>G p.T457A | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2
- GRAMD1C | c.485G>T p.R162M | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRM5 | c.2280G>T p.K760N | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HDAC8 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- HEATR5A | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEATR5A | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ICE1 | c.3838A>G p.K1280E | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- IGKV6D-21 | c.106del p.E36Rfs*? | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, varscan2
- IGSF1 | c.887G>C p.C296S | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- IL18R1 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2
- KALRN | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 36/471 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIAA1217 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2
- KRT6A | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 92/673 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- LPXN | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- LRBA | c.4135C>A p.L1379I | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRRTM4 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.024); called by muse, mutect2
- MAP7D3 | c.2396G>T p.R799L | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2
- MC3R | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MICAL3 | c.4259G>T p.R1420M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2
- MTMR1 | c.1408G>C p.V470L | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2
- MTR | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MUC1 | c.3209C>T p.T1070I (on ENST00000611571 / NM_001371720.1; = p.T81I on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYLK2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO18B | c.3005T>C p.L1002P | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2
- NOLC1 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10J5 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- OR10K1 | c.814A>T p.T272S | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR14K1 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); called by muse, mutect2
- OR4K1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 33/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- OR5L2 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.047); called by muse, mutect2
- OR8H1 | c.885A>T p.E295D | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- PCDH7 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PDE1B | c.1193A>T p.K398M | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDS5B | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.221); called by muse, mutect2
- PDZD11 | c.-12G>T | Splice Region (SNP) | VAF 20/169 reads (12%) | called by muse, varscan2
- PFKFB3 | c.173A>T p.Y58F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | PolyPhen possibly damaging (0.843); called by muse, mutect2
- PLEKHA5 | c.2086G>C p.D696H | Missense Mutation (SNP) | VAF 32/443 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PRKCA | c.1323-1G>C p.X441_splice | Splice Site (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- PROKR2 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR23A | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- RALB | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RASAL1 | c.2390C>A p.A797E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR2 | c.9019C>A p.L3007I | Missense Mutation (SNP) | VAF 25/525 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2
- SCD | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCMH1 | c.595G>C p.V199L (on ENST00000326197 / NM_001031694.2; = p.V152L on NM_012236.4) | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SIM1 | c.1149G>T p.R383S | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLITRK2 | c.2446A>T p.K816* | Nonsense Mutation (SNP) | VAF 19/222 reads (9%) | called by muse, mutect2
- SPECC1 | c.3063G>C p.R1021S | Missense Mutation (SNP) | VAF 17/420 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SPINK7 | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 38/408 reads (9%) | called by muse, mutect2
- SRBD1 | c.2457G>T p.K819N | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAT2 | c.101A>T p.Y34F | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SULT1E1 | c.460T>A p.F154I | Missense Mutation (SNP) | VAF 47/562 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2
- SYNE2 | c.8896G>A p.E2966K | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBC1D32 | c.3053G>T p.R1018M | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- TECRL | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 26/790 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2
- TENM1 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- THOC2 | c.3554A>G p.E1185G | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2
- THOC2 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRO | c.2900C>A p.A967D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TRPM8 | c.204C>A p.C68* | Nonsense Mutation (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- UNC80 | c.2452C>G p.L818V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- VSIG1 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.42); called by muse, mutect2
- WFDC3 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIAP | c.1108A>G p.I370V | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- ZFYVE9 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZIC4 | c.-15G>T | Splice Region (SNP) | VAF 17/250 reads (7%) | called by muse, mutect2
- ZNF630 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ZNF761 | c.1888G>T p.G630* | Nonsense Mutation (SNP) | VAF 32/311 reads (10%) | called by muse, mutect2
- ZNF761 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ADPRM | c.792C>G p.V264= | Silent (SNP) | VAF 19/336 reads (6%) | called by muse, mutect2
- ANKRD36 | c.1701C>G p.A567= | Silent (SNP) | VAF 17/309 reads (6%) | catalogued as COSV101347268; called by muse, mutect2
- BTNL2 | c.117G>T p.L39= | Silent (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- CCDC189 | c.444C>A p.L148= | Silent (SNP) | VAF 20/330 reads (6%) | catalogued as COSV100079864; called by muse, mutect2
- CD40LG | c.567T>C p.F189= | Silent (SNP) | VAF 30/282 reads (11%) | catalogued as rs1449662238; called by muse, mutect2, varscan2
- CIDEA | c.139C>A p.R47= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- DLL1 | c.333C>T p.P111= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs1325862736; called by muse, mutect2
- DOCK4 | c.2952A>G p.L984= | Silent (SNP) | VAF 41/268 reads (15%) | catalogued as rs1048321032; called by muse, mutect2, varscan2
- DUSP9 | c.960C>A p.V320= | Silent (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- ENOX2 | c.1098T>A p.A366= (on ENST00000338144 / NM_001382520.1; = p.A337= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- ESPL1 | c.201C>T p.C67= | Silent (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- FGF6 | c.243G>T p.G81= | Silent (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- GPX5 | c.528C>A p.V176= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV69079986; called by muse, mutect2
- INPP4A | c.1848C>T p.P616= (on ENST00000074304 / NM_001134224.1; = p.P577= on NM_001566.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/239 reads (6%) | catalogued as rs1270142241; called by muse, mutect2
- KCND1 | c.1584G>T p.L528= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV99502080; called by muse, mutect2, varscan2
- KCTD19 | c.813C>T p.P271= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs369409867; called by mutect2, varscan2
- KRT24 | c.516C>A p.I172= | Silent (SNP) | VAF 13/194 reads (7%) | catalogued as COSV52880842; called by muse, mutect2
- LHFPL5 | c.372C>A p.A124= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- LOXL1 | c.1545C>T p.D515= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- MAB21L3 | c.582C>T p.P194= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- MTR | c.99G>T p.L33= | Silent (SNP) | VAF 26/455 reads (6%) | called by muse, mutect2
- MYO18B | c.3006C>T p.L1002= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as COSV59128601; called by muse, mutect2
- NOX3 | c.825G>T p.V275= | Silent (SNP) | VAF 28/345 reads (8%) | called by muse, mutect2
- OR2T1 | c.84C>A p.A28= | Silent (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- OR5F1 | c.642C>A p.I214= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- PARD3 | c.2736G>T p.R912= | Silent (SNP) | VAF 27/351 reads (8%) | called by muse, mutect2
- PCDHA1 | c.1983C>T p.A661= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- PCTP | c.150A>T p.G50= | Silent (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- PFKM | c.1110C>T p.A370= | Silent (SNP) | VAF 36/216 reads (17%) | catalogued as COSV56659857; called by muse, mutect2, varscan2
- PLG | c.1065C>T p.S355= | Silent (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- PTGFRN | c.1932G>A p.Q644= | Silent (SNP) | VAF 18/325 reads (6%) | called by muse, mutect2
- RAD51C | c.786A>G p.L262= | Silent (SNP) | VAF 43/426 reads (10%) | called by muse, mutect2, varscan2
- RNF112 | c.1593G>T p.T531= | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- ROBO2 | c.48T>G p.A16= | Silent (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- SETD5 | c.2694T>G p.A898= | Silent (SNP) | VAF 40/345 reads (12%) | called by muse, mutect2, varscan2
- SPHKAP | c.3642G>T p.R1214= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV60870005; called by muse, mutect2
- STARD9 | c.2991G>T p.G997= | Silent (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- SULF1 | c.2478C>T p.H826= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as rs757079996; called by muse, mutect2
- TYK2 | c.720G>A p.R240= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- UTRN | c.7464C>G p.L2488= | Silent (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2
- WDR53 | c.138G>T p.T46= | Silent (SNP) | VAF 15/201 reads (7%) | catalogued as COSV60283880; called by muse, mutect2
- ZCCHC18 | c.969C>A p.T323= | Silent (SNP) | VAF 21/203 reads (10%) | called by muse, mutect2, varscan2
- ZNF233 | c.1080T>C p.H360= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- AC139769.1 | n.214-3822G>T | Intron (SNP) | VAF 15/287 reads (5%) | called by muse, mutect2
- ACTB | c.364-20G>A | Intron (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- AL353804.4 | chrX:73825390 C>T | 5'Flank (SNP) | VAF 24/360 reads (7%) | catalogued as rs769471195; called by muse, mutect2
- ATRIP | c.*7G>T | 3'UTR (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- CEP170P1 | n.1781G>A | RNA (SNP) | VAF 30/555 reads (5%) | called by muse, mutect2
- CLCC1 | c.-92G>C | 5'UTR (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- COMMD7 | c.526+169G>T | Intron (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- CRISP2 | c.515+167A>G | Intron (SNP) | VAF 23/332 reads (7%) | called by muse, mutect2
- CRPPA | c.*2179C>T | 3'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, varscan2
- CTSK | c.619-27G>T | Intron (SNP) | VAF 13/358 reads (4%) | called by muse, mutect2
- ING2 | c.172+945G>T | Intron (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- LAMA2 | c.6086-15C>G | Intron (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- MAMLD1 | c.-6C>A | 5'UTR (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- MIR891B | n.56A>C | RNA (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- MYO19 | c.894+25A>C | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- NECTIN3 | c.160+5078G>C | Intron (SNP) | VAF 30/369 reads (8%) | called by muse, mutect2
- PARVB | c.693-38G>T | Intron (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- PRKCH | c.363+4552G>T | Intron (SNP) | VAF 12/76 reads (16%) | called by muse, varscan2
- RAB11FIP5 | c.*10C>A | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- REG1A | c.183+76G>T | Intron (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- RORC | c.70+3471C>T | Intron (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- SYT14 | chr1:210163465 C>A | 3'Flank (SNP) | VAF 37/532 reads (7%) | called by muse, mutect2
- TAFA5 | c.263-14366C>A | Intron (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2, varscan2
- TSPAN9 | c.648+84G>T | Intron (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- TTN | c.10361-4862T>C | Intron (SNP) | VAF 84/841 reads (10%) | catalogued as rs765093886; called by muse, mutect2, varscan2
- ZDHHC3 | c.*8626G>C | 3'UTR (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- ZNF7 | c.-28C>T | 5'UTR (SNP) | VAF 43/233 reads (18%) | catalogued as rs1377179075; called by muse, mutect2, varscan2
- ZNF812P | n.1282T>A | RNA (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
